Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAGF, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAGF-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Left orchidectomy; nonseminoma (MT + IT 50%, EC 40%, YST 5%, trophoblastic giant cells 5%); diameter 4 cm; tumor confined to testis; angio-invasion present; invasion of rete testis present.

Date of procurement (= date of orchidectomy):

Mixed germ cell tumor
908513
Site: ① Testis NOS
② 629
JH 3/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 3d762e7b-9ade-42d5-a929-16f064cfaab1 (TCGA-2G-AAGF.B1C73195-FD0D-4FCA-AB2E-ABB9FD4F1EA9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).